Somatic mutation profile of tumor specimen MP2PRT-PAVDCZ-TBP1-A (aliquot MP2PRT-PAVDCZ-TBP1-A-1-0-D-A835-36) from MP2PRT case MP2PRT-PAVDCZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 10.3 years (3,755 days).
Specimen MP2PRT-PAVDCZ-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72b1fd8a-472c-4303-96e4-7e12eab502d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVDCZ-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVDCZ-NM1-A-1-0-D-A835-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f327c57f-03c5-4513-bb2b-c3764be533ab

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, Nonsense Mutation 1, Translation Start Site 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A5 | c.4688G>A p.R1563Q | Missense Mutation (SNP) | VAF 106/224 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs281874743, CM931217, CS961525, COSV100087041; ClinVar: pathogenic; called by muse, varscan2
- COL11A2 | c.2062G>A p.G688R (on ENST00000341947 / NM_080680.3; = p.G581R on NM_080679.2) | Missense Mutation (SNP) | VAF 178/666 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs754930743, COSV59496916; called by muse, varscan2
- DST | c.21650G>A p.R7217Q (on ENST00000361203 / NM_001374722.1; = p.R4914Q on NM_015548.5) | Missense Mutation (SNP) | VAF 64/381 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs920975458; called by muse, mutect2, varscan2
- FIGNL2 | c.986C>G p.P329R | Missense Mutation (SNP) | VAF 250/604 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.052); catalogued as rs770601764; called by muse, varscan2
- MOGAT1 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 94/276 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs201195571, COSV71480187; called by muse, varscan2
- MUC15 | c.934C>A p.P312T | Missense Mutation (SNP) | VAF 112/453 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); catalogued as COSV99029012; called by muse, mutect2, varscan2
- PCDHGA5 | c.1111G>A p.V371I | Missense Mutation (SNP) | VAF 141/495 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.358); catalogued as rs749640886, COSV53974505; called by muse, mutect2, varscan2
- SORBS2 | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 153/563 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52989839; called by muse, mutect2, varscan2
- CCDC27 | c.11C>A p.A4D | Missense Mutation (SNP) | VAF 80/243 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.503); called by muse, varscan2
- CREBBP | c.5282_5283insCC p.K1762Qfs*10 | Frame Shift Ins (INS) | VAF 203/816 reads (25%) | called by mutect2, pindel, varscan2
- DOT1L | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 165/416 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXO1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 216/585 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.011); called by muse, varscan2
- MTO1 | c.406C>A p.Q136K | Missense Mutation (SNP) | VAF 82/289 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OLFML2B | c.1576G>T p.E526* | Nonsense Mutation (SNP) | VAF 94/450 reads (21%) | called by muse, mutect2, varscan2
- OR4A15 | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 240/430 reads (56%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PPP1R3D | c.380T>A p.V127E | Missense Mutation (SNP) | VAF 180/480 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, varscan2
- SORCS1 | c.3435G>T p.L1145F | Missense Mutation (SNP) | VAF 82/388 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.969); called by mutect2, varscan2
- SYDE1 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 183/490 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.075); called by muse, varscan2
- APBA1 | c.717C>T p.D239= | Silent (SNP) | VAF 90/550 reads (16%) | catalogued as rs773533052; called by muse, varscan2
- CFAP65 | c.2322C>A p.I774= | Silent (SNP) | VAF 105/304 reads (35%) | called by muse, varscan2
- FAM171A1 | c.1899C>T p.I633= | Silent (SNP) | VAF 168/890 reads (19%) | called by muse, mutect2, varscan2
- GRM1 | c.3291C>T p.D1097= | Silent (SNP) | VAF 24/870 reads (3%) | called by muse, mutect2
- SLIT2 | c.4566C>T p.C1522= | Silent (SNP) | VAF 89/362 reads (25%) | catalogued as rs200637778; called by muse, mutect2, varscan2
- ZNF556 | c.486G>C p.L162= | Silent (SNP) | VAF 126/342 reads (37%) | catalogued as COSV100298735; called by muse, mutect2, varscan2
- IGHV3-23 | chr14:106268605 ins TTCCTTA | 3'Flank (INS) | VAF 18/186 reads (10%) | called by mutect2, pindel*
